Gene-level copy-number profile of tumor specimen TCGA-04-1651-01A from TCGA case TCGA-04-1651, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 53.7 years (19,628 days).
Specimen TCGA-04-1651-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.5ce5aabb-61c2-484f-9fd2-be3da4e1242f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-04-1651-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c627b430-d21d-4615-b4f1-a92e37955cc2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 51; copy number 1: 19,898; copy number 2: 33,859; copy number 3: 4,770; copy number 4: 1,188; copy number 5: 53.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-04-1651-01A-01D-0577-01): tumor purity 0.92, ploidy 1.76, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 51 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:20,582,072–20,590,085, 2 genes: EEF1A1P27, AC002486.2.
- chr13:48,488,963–50,125,720, 43 genes: RCBTB2, AL157813.2, AL157813.1, LINC01077, LINC00462, CYSLTR2, PSME2P2, AL161421.1, FNDC3A, RNU6-60P, RAD17P2, RNY3P2, COX7CP1, OGFOD1P1, MLNR, AL137000.1, CDADC1, CAB39L, SETDB2, SNRPGP14, PHF11, RCBTB1, AL135901.1, ARL11, EBPL, KPNA3, AL136301.1, RNY4P30, CTAGE10P, RNY4P9, SPRYD7, DLEU2, TRIM13, MIR3613, KCNRG, AL137060.9, AL137060.7, MIR16-1, MIR15A, AL137060.4, AL137060.2, AL137060.8, AL137060.5.
- chr13:50,082,295–50,173,181, 5 genes: AL137060.6, RPL18P10, AL137060.1, AL137060.3, ST13P4.
- chr13:80,011,077–80,028,283, 1 gene: LINC01080.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 53 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:196,639,694–198,222,513, 53 genes, copy number 5: NRROS, PIGX, CEP19, RNU6-646P, PAK2, RNU4-89P, RNU6-42P, SENP5, AC016949.1, NCBP2, NCBP2-AS1, NCBP2AS2, PIGZ, AC011322.1, RPSAP69, MELTF, MELTF-AS1, DLG1, MIR4797, DLG1-AS1, AL121981.1, AC128709.2, AC128709.1, AC128709.3, LINC02012, BDH1, AC132008.2, AC132008.1, AC024560.2, AC024560.3, AC024560.4, AC024560.1, AC024560.5, RUBCN, MIR922, FYTTD1, AC055764.2, LRCH3, AC055764.1, AC144530.1, IQCG, RNU6-858P, RPL35A, LMLN, RNU6-621P, AC135893.1, LMLN-AS1, ANKRD18DP, RNU6-821P, FRG2FP, TUBB8P8, AC073135.1, FAM157A.

Autosomal genes at a single copy (total copy number 1): 19,898. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
